Somatic mutation profile of tumor specimen MMRF_1787_1_BM_CD138pos (aliquot MMRF_1787_1_BM_CD138pos_T1_KBS5U_L05075) from MMRF case MMRF_1787, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 70.9 years (25,884 days).
Specimen MMRF_1787_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cf9aa64c-fa1f-42df-9341-9e085517e4df.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1787_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1787_1_PB_Whole_C2_KBS5U_L05083; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d364c870-7246-40be-9506-8da6f6773b9f

The open-access MAF lists 105 somatic variants for this specimen: 38 protein-altering or splice-affecting, 12 silent, 55 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, 3'UTR 31, Intron 13, Silent 12, 5'UTR 4, 3'Flank 3, Nonsense Mutation 3, 5'Flank 2, RNA 2, Frame Shift Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 37/70 reads (53%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.03); PolyPhen benign (0.1); catalogued as rs121913499, CM1111831, COSV61615256, COSV61615456, COSV61615649; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ANKFN1 | c.3448C>T p.R1150W (on ENST00000653862; = p.R1003W on NM_001365758.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 116/227 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as rs1256527835, COSV73719534; called by muse, mutect2, varscan2
- CACNA1H | c.2842G>A p.G948R | Missense Mutation (SNP) | VAF 81/151 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs763407611, COSV61995482; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDH18 | c.34G>C p.V12L | Missense Mutation (SNP) | VAF 126/313 reads (40%) | SIFT tolerated (0.46); PolyPhen benign (0.036); catalogued as COSV99937921; called by muse, mutect2, varscan2
- FAM124B | c.343G>T p.E115* | Nonsense Mutation (SNP) | VAF 97/196 reads (49%) | catalogued as rs527479715, COSV66271821; called by muse, mutect2, varscan2
- FAM83H | c.2006G>A p.R669H | Missense Mutation (SNP) | VAF 28/40 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1554622582; called by muse, mutect2, varscan2
- GIN1 | c.1361C>T p.P454L | Missense Mutation (SNP) | VAF 147/287 reads (51%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.196); catalogued as rs200335348, COSV67536672; called by muse, mutect2, varscan2
- HLX | c.838C>T p.R280C | Missense Mutation (SNP) | VAF 80/240 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65045583; called by muse, mutect2, varscan2
- IGSF8 | c.281G>A p.R94Q | Missense Mutation (SNP) | VAF 136/351 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs755867439; called by muse, mutect2, varscan2
- INTS5 | c.2457T>A p.S819R | Missense Mutation (SNP) | VAF 62/136 reads (46%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.743); catalogued as rs776493392; called by muse, varscan2
- ITGAX | c.1151C>A p.P384Q | Missense Mutation (SNP) | VAF 71/128 reads (55%) | SIFT tolerated (0.26); PolyPhen benign (0.04); catalogued as COSV99191611; called by muse, mutect2, varscan2
- MUC4 | c.6335C>T p.A2112V | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.494); catalogued as rs1169934136; called by muse, mutect2, varscan2
- OTOGL | c.4786T>C p.S1596P (on ENST00000547103; = p.S1587P on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT tolerated (0.5); PolyPhen benign (0.006); catalogued as rs1239494866; called by muse, mutect2, varscan2
- OVGP1 | c.503G>A p.R168Q | Missense Mutation (SNP) | VAF 12/115 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs746838196; called by muse, mutect2, varscan2
- SCN8A | c.4886G>A p.R1629H | Missense Mutation (SNP) | VAF 94/170 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs376631260; called by muse, mutect2, varscan2
- SPATA31D1 | c.3295G>T p.E1099* | Nonsense Mutation (SNP) | VAF 45/107 reads (42%) | catalogued as COSV61193279; called by muse, mutect2, varscan2
- ABCC8 | c.1817+4A>C | Splice Region (SNP) | VAF 29/58 reads (50%) | called by muse, mutect2, varscan2
- C9orf64 | c.509G>A p.C170Y | Missense Mutation (SNP) | VAF 122/259 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- CEP295 | c.7189G>C p.E2397Q | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- CRIPT | c.162G>T p.K54N | Missense Mutation (SNP) | VAF 36/61 reads (59%) | SIFT tolerated (0.24); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- CST2 | c.147C>A p.H49Q | Missense Mutation (SNP) | VAF 43/94 reads (46%) | SIFT tolerated (0.43); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- DTNBP1 | c.800C>T p.S267F | Missense Mutation (SNP) | VAF 85/246 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- EXOSC4 | c.521G>A p.S174N | Missense Mutation (SNP) | VAF 60/110 reads (55%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- HSPA8 | c.1843G>T p.G615* | Nonsense Mutation (SNP) | VAF 50/117 reads (43%) | called by muse, mutect2, varscan2
- IGHV2-70D | c.275A>C p.K92T | Missense Mutation (SNP) | VAF 51/95 reads (54%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.924); called by muse, varscan2
- IGHV2-70D | c.234A>T p.K78N | Missense Mutation (SNP) | VAF 66/115 reads (57%) | SIFT tolerated (0.06); PolyPhen benign (0.019); called by muse, varscan2
- IGHV2-70D | c.34A>C p.T12P | Missense Mutation (SNP) | VAF 40/154 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, varscan2
- KDM3A | c.2764G>A p.D922N | Missense Mutation (SNP) | VAF 37/79 reads (47%) | SIFT tolerated (0.21); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- KLF4 | c.1201G>A p.A401T | Missense Mutation (SNP) | VAF 75/151 reads (50%) | SIFT tolerated (0.17); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- OR10W1 | c.727T>C p.Y243H | Missense Mutation (SNP) | VAF 48/94 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.314); called by muse, mutect2, varscan2
- PARM1 | c.592G>A p.E198K | Missense Mutation (SNP) | VAF 265/420 reads (63%) | SIFT deleterious (0.03); PolyPhen benign (0.046); called by muse, mutect2
- PCDH11Y | c.3793G>T p.A1265S | Missense Mutation (SNP) | VAF 150/156 reads (96%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- PECR | c.602C>A p.P201H | Missense Mutation (SNP) | VAF 56/126 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- SPATA31D1 | c.3106A>G p.K1036E | Missense Mutation (SNP) | VAF 148/291 reads (51%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- STOML1 | c.689C>T p.P230L | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT tolerated (0.33); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TDRD15 | c.3245dup p.L1082Ffs*5 | Frame Shift Ins (INS) | VAF 38/96 reads (40%) | called by mutect2, pindel, varscan2
- TRIL | c.167C>T p.P56L | Missense Mutation (SNP) | VAF 16/155 reads (10%) | SIFT tolerated (0.37); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TUT7 | c.3944T>C p.V1315A | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.684); called by muse, mutect2, varscan2
- APAF1 | c.3490T>C p.L1164= (on ENST00000551964 / NM_181861.2; = p.L1110= on NM_001160.3) | Silent (SNP) | VAF 49/92 reads (53%) | catalogued as rs1320545417; called by muse, mutect2, varscan2
- ARRDC1 | c.174A>G p.T58= | Silent (SNP) | VAF 107/185 reads (58%) | called by muse, mutect2, varscan2
- CHD4 | c.2661G>C p.L887= (on ENST00000357008 / NM_001363606.2; = p.L900= on NM_001273.5) | Silent (SNP) | VAF 98/190 reads (52%) | catalogued as rs773003594; called by muse, mutect2, varscan2
- ERFE | c.861C>T p.C287= | Silent (SNP) | VAF 19/28 reads (68%) | catalogued as rs1266366154; called by muse, mutect2, varscan2
- FLRT2 | c.1008T>A p.G336= | Silent (SNP) | VAF 12/189 reads (6%) | called by muse, mutect2
- GMCL2 | c.495G>A p.A165= | Silent (SNP) | VAF 48/114 reads (42%) | catalogued as rs774008340; called by muse, mutect2, varscan2
- GREB1L | c.1201C>T p.L401= | Silent (SNP) | VAF 71/143 reads (50%) | called by muse, mutect2, varscan2
- IGHV2-70D | c.327G>A p.V109= | Silent (SNP) | VAF 14/60 reads (23%) | called by muse, varscan2
- LYZL1 | c.327G>T p.T109= (on ENST00000375500; = p.T63= on NM_032517.6) | Silent (SNP) | VAF 92/208 reads (44%) | catalogued as COSV64966225; called by muse, mutect2, varscan2
- MUC19 | c.105T>C p.P35= | Silent (SNP) | VAF 88/194 reads (45%) | called by muse, mutect2, varscan2
- RNF223 | c.81C>G p.S27= | Silent (SNP) | VAF 39/86 reads (45%) | called by muse, mutect2, varscan2
- TOLLIP | c.108C>T p.D36= | Silent (SNP) | VAF 41/72 reads (57%) | catalogued as rs369325002; called by muse, mutect2, varscan2
- ABCB11 | c.*355G>C | 3'UTR (SNP) | VAF 34/73 reads (47%) | called by muse, mutect2, varscan2
- AC011410.1 | n.58C>T | RNA (SNP) | VAF 109/236 reads (46%) | called by muse, mutect2, varscan2
- ADCY6 | c.*1762G>A | 3'UTR (SNP) | VAF 68/139 reads (49%) | called by muse, mutect2, varscan2
- ATXN1 | c.*4490T>C | 3'UTR (SNP) | VAF 8/208 reads (4%) | catalogued as rs1175885716; called by muse, mutect2
- CAMKV | c.*1099G>T | 3'UTR (SNP) | VAF 66/119 reads (55%) | called by muse, mutect2, varscan2
- CLEC1A | c.*1114del | 3'UTR (DEL) | VAF 36/98 reads (37%) | called by mutect2, pindel, varscan2
- CNTN1 | c.*1476G>A | 3'UTR (SNP) | VAF 82/174 reads (47%) | called by muse, mutect2, varscan2
- CPLANE1 | c.8796+136A>G | Intron (SNP) | VAF 36/66 reads (55%) | called by muse, mutect2, varscan2
- CTBP1 | chr4:1250055 T>A | 5'Flank (SNP) | VAF 41/89 reads (46%) | catalogued as rs1300142118; called by muse, mutect2, varscan2
- CXCR4 | c.16-224T>C | Intron (SNP) | VAF 34/64 reads (53%) | called by muse, varscan2
- CXCR4 | c.16-277T>C | Intron (SNP) | VAF 26/48 reads (54%) | called by muse, varscan2
- DCC | c.*3519T>A | 3'UTR (SNP) | VAF 44/90 reads (49%) | called by muse, mutect2, varscan2
- DMP1 | c.*774A>C | 3'UTR (SNP) | VAF 35/81 reads (43%) | called by muse, mutect2, varscan2
- DNM1P46 | n.933G>A | RNA (SNP) | VAF 18/42 reads (43%) | catalogued as rs1439364012; called by muse, mutect2, varscan2
- ELP4 | chr11:31788333 T>C | 3'Flank (SNP) | VAF 74/142 reads (52%) | called by muse, mutect2, varscan2
- EPG5 | c.3240-38A>T | Intron (SNP) | VAF 110/215 reads (51%) | called by muse, mutect2, varscan2
- FAT3 | c.*4045G>A | 3'UTR (SNP) | VAF 23/55 reads (42%) | catalogued as rs576918332; called by muse, mutect2, varscan2
- FGR | chr1:27612458 G>T | 3'Flank (SNP) | VAF 49/101 reads (49%) | called by muse, mutect2, varscan2
- FOXJ3 | c.*2864G>C | 3'UTR (SNP) | VAF 9/183 reads (5%) | called by muse, mutect2
- G3BP1 | c.742-24G>T | Intron (SNP) | VAF 23/59 reads (39%) | called by muse, mutect2, varscan2
- GABRQ | c.*985C>T | 3'UTR (SNP) | VAF 70/71 reads (99%) | called by muse, mutect2, varscan2
- GOLPH3 | c.*939G>A | 3'UTR (SNP) | VAF 34/89 reads (38%) | called by muse, mutect2, varscan2
- HS3ST3B1 | c.*1354C>T | 3'UTR (SNP) | VAF 42/87 reads (48%) | called by muse, mutect2, varscan2
- ICA1L | c.*1628C>T | 3'UTR (SNP) | VAF 6/12 reads (50%) | called by muse, mutect2, varscan2
- LEKR1 | c.*1053G>C | 3'UTR (SNP) | VAF 84/187 reads (45%) | catalogued as COSV62962044; called by muse, mutect2, varscan2
- LPCAT2 | c.*1579G>T | 3'UTR (SNP) | VAF 71/149 reads (48%) | called by muse, mutect2, varscan2
- LTB | c.208+74A>C | Intron (SNP) | VAF 227/312 reads (73%) | called by muse, varscan2
- LTB | c.163-41G>A | Intron (SNP) | VAF 536/714 reads (75%) | catalogued as rs4647183, COSV53001370; called by muse, mutect2, varscan2
- MAP2K3 | c.*639T>A | 3'UTR (SNP) | VAF 12/37 reads (32%) | catalogued as rs932250173; called by muse, mutect2, varscan2
- MDS2 | chr1:23627318 del A | 5'Flank (DEL) | VAF 14/140 reads (10%) | called by mutect2, pindel, varscan2
- MYC | c.-60G>C | 5'UTR (SNP) | VAF 64/118 reads (54%) | called by muse, mutect2, varscan2
- MYO5A | c.*1813A>C | 3'UTR (SNP) | VAF 38/137 reads (28%) | called by muse, mutect2, varscan2
- NEUROD1 | c.*623A>C | 3'UTR (SNP) | VAF 12/22 reads (55%) | called by muse, mutect2, varscan2
- PCDH15 | c.*670T>G | 3'UTR (SNP) | VAF 55/125 reads (44%) | called by muse, mutect2, varscan2
- PITRM1 | c.2236-111_2236-100delinsT | Intron (DEL) | VAF 15/21 reads (71%) | called by pindel, varscan2*
- PLPPR4 | c.-444A>T | 5'UTR (SNP) | VAF 30/62 reads (48%) | called by muse, mutect2, varscan2
- POU3F4 | c.*154del | 3'UTR (DEL) | VAF 34/47 reads (72%) | called by mutect2, pindel, varscan2
- PRRX1 | c.599+42T>C | Intron (SNP) | VAF 80/128 reads (63%) | catalogued as rs1300648415; called by muse, mutect2, varscan2
- PTCHD1 | c.*1871T>C | 3'UTR (SNP) | VAF 40/42 reads (95%) | called by muse, mutect2, varscan2
- RBBP7 | c.-56C>T | 5'UTR (SNP) | VAF 10/87 reads (11%) | catalogued as rs1161290809, COSV101198321; called by muse, mutect2, varscan2
- RINT1 | c.-70C>A | 5'UTR (SNP) | VAF 32/65 reads (49%) | catalogued as COSV57557102; called by muse, mutect2, varscan2
- RNF217 | c.1116+2796T>C | Intron (SNP) | VAF 129/130 reads (99%) | called by muse, mutect2, varscan2
- SEMA3C | c.*2132A>C | 3'UTR (SNP) | VAF 43/83 reads (52%) | called by muse, mutect2, varscan2
- SLITRK2 | chrX:145828201 T>A | 3'Flank (SNP) | VAF 6/41 reads (15%) | called by muse, mutect2, varscan2
- SLITRK4 | c.*161G>A | 3'UTR (SNP) | VAF 30/30 reads (100%) | catalogued as COSV100567329, COSV100567381; called by muse, mutect2, varscan2
- SYBU | c.*648T>C | 3'UTR (SNP) | VAF 36/76 reads (47%) | called by muse, mutect2, varscan2
- SYNE3 | c.1776+494C>T | Intron (SNP) | VAF 18/42 reads (43%) | called by muse, mutect2
- SYNE3 | c.1776+492C>T | Intron (SNP) | VAF 18/42 reads (43%) | called by muse, mutect2
- TBC1D9 | c.*573C>T | 3'UTR (SNP) | VAF 23/71 reads (32%) | called by muse, mutect2, varscan2
- THAP11 | c.*511del | 3'UTR (DEL) | VAF 29/80 reads (36%) | called by mutect2, pindel, varscan2
- TMPRSS11F | c.*330C>T | 3'UTR (SNP) | VAF 46/97 reads (47%) | called by muse, mutect2, varscan2
- TRPM1 | c.1197+110G>T | Intron (SNP) | VAF 34/56 reads (61%) | called by mutect2, varscan2
- USP49 | c.*2058A>G | 3'UTR (SNP) | VAF 19/38 reads (50%) | called by muse, mutect2, varscan2
- VPS54 | c.*654C>T | 3'UTR (SNP) | VAF 5/11 reads (45%) | called by muse, mutect2
- ZNF713 | c.*595C>T | 3'UTR (SNP) | VAF 13/21 reads (62%) | called by muse, mutect2, varscan2
